FM case AD4024 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/028b9e84-f8a7-46c1-914b-f1aa9675774e

Male, 56.0 years: Carcinoma, NOS (ICD-O-3 8010/3) of the major salivary gland; specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
